Somatic mutation profile of tumor specimen MP2PRT-PARGFF-TBP1-A (aliquot MP2PRT-PARGFF-TBP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARGFF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 3.6 years (1,307 days).
Specimen MP2PRT-PARGFF-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5fd7b6d-48d4-4d78-b10a-fd4b812dc372.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARGFF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARGFF-NB1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1205423-4604-4c92-806e-b6c6de139dfd

The open-access MAF lists 38 somatic variants for this specimen: 20 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 15, Missense Mutation 15, Intron 3, Nonsense Mutation 3, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 53/256 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADO | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 106/1272 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV65677673; called by muse, mutect2
- ATAD5 | c.3535C>G p.Q1179E | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1244033902; called by muse, mutect2
- CEP131 | c.716C>G p.S239* | Nonsense Mutation (SNP) | VAF 68/581 reads (12%) | catalogued as COSV99487774, COSV99488398; called by muse, mutect2, varscan2
- COL6A3 | c.872G>T p.R291I | Missense Mutation (SNP) | VAF 141/335 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV55085771; called by muse, mutect2, varscan2
- CTCF | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 20/284 reads (7%) | catalogued as COSV50461476; called by muse, mutect2
- ELAVL4 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV63914869; called by muse, mutect2, varscan2
- FSTL5 | c.1646A>G p.Y549C | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1460696694; called by muse, mutect2, varscan2
- MUC4 | c.12721C>G p.L4241V | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.316); catalogued as rs1198133325, COSV57807427; called by muse, varscan2
- OTUD4 | c.442C>G p.H148D (on ENST00000447906 / NM_001366057.1; = p.H83D on NM_017493.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56851735; called by muse, mutect2, varscan2
- TMEM132D | c.1042C>G p.R348G | Missense Mutation (SNP) | VAF 181/481 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV70598035; called by muse, mutect2, varscan2
- TMPRSS9 | c.2944C>T p.R982C (on ENST00000648592; = p.R948C on NM_182973.2) | Missense Mutation (SNP) | VAF 237/556 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1238038923; called by muse, mutect2, varscan2
- AHDC1 | c.4638G>C p.L1546F | Missense Mutation (SNP) | VAF 57/902 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- CARD14 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 52/764 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2
- CNOT6L | c.312C>T p.L104= (on ENST00000504123 / NM_001286790.2; = p.L99= on NM_144571.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2, varscan2
- IGHV4-59 | c.349_350insGGGGAGAG | In Frame Ins (INS) | VAF 5/32 reads (16%) | called by mutect2, varscan2
- IGKV1OR2-108 | chr2:113406870 ATTCACAGTGTTACA>CCTT | Missense Mutation (DEL) | VAF 36/102 reads (35%) | called by pindel, varscan2*
- PHLDB2 | c.1140G>C p.R380S | Missense Mutation (SNP) | VAF 56/329 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ROBO1 | c.3685G>A p.E1229K | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- UBA2 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 40/296 reads (14%) | called by muse, mutect2, varscan2
- ABCA9 | c.2490C>T p.H830= | Silent (SNP) | VAF 121/347 reads (35%) | catalogued as rs750381974, COSV60619702; called by muse, mutect2, varscan2
- CCSER1 | c.1080G>A p.V360= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as rs761424550, COSV100395115; called by muse, mutect2, varscan2
- DPH2 | c.216G>A p.T72= | Silent (SNP) | VAF 102/255 reads (40%) | catalogued as rs1160419691; called by muse, mutect2, varscan2
- ENG | c.1725C>T p.I575= | Silent (SNP) | VAF 42/465 reads (9%) | catalogued as rs1333193699, COSV61229156; called by muse, mutect2
- GLTPD2 | c.354C>G p.L118= | Silent (SNP) | VAF 46/471 reads (10%) | called by muse, mutect2, varscan2
- GPR101 | c.768C>T p.F256= | Silent (SNP) | VAF 129/947 reads (14%) | catalogued as rs761882471; called by muse, mutect2, varscan2
- MKRN3 | c.537C>T p.F179= | Silent (SNP) | VAF 270/581 reads (46%) | catalogued as rs574676138; called by muse, mutect2, varscan2
- PCDHGA3 | c.1722C>T p.G574= | Silent (SNP) | VAF 463/1064 reads (44%) | catalogued as rs1407265587, COSV53940121; called by muse, mutect2, varscan2
- PRAMEF10 | c.1311G>C p.L437= | Silent (SNP) | VAF 8/268 reads (3%) | catalogued as rs373634947, COSV99338857; called by muse, mutect2
- RHCG | c.273C>T p.F91= | Silent (SNP) | VAF 48/604 reads (8%) | catalogued as rs761017965; called by muse, mutect2
- TBX15 | c.1689G>A p.E563= (on ENST00000369429 / NM_001330677.2; = p.E457= on NM_152380.3) | Silent (SNP) | VAF 59/350 reads (17%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.33C>T p.G11= | Silent (SNP) | VAF 60/884 reads (7%) | catalogued as rs560232466, COSV60976350; called by muse, mutect2
- TUBB8 | c.1101C>T p.F367= | Silent (SNP) | VAF 58/368 reads (16%) | called by muse, mutect2, varscan2
- ZFHX4 | c.201G>A p.E67= | Silent (SNP) | VAF 26/318 reads (8%) | catalogued as COSV50480130; called by muse, mutect2
- ZSWIM9 | c.36G>A p.A12= | Silent (SNP) | VAF 282/719 reads (39%) | catalogued as rs1173546563; called by muse, mutect2, varscan2
- ANKRD17 | c.393+35263G>A | Intron (SNP) | VAF 48/143 reads (34%) | catalogued as rs567386200; called by muse, mutect2, varscan2
- C1orf105 | c.199-3287C>A | Intron (SNP) | VAF 101/285 reads (35%) | called by muse, mutect2, varscan2
- PRKAG2 | c.466+45234G>C | Intron (SNP) | VAF 63/441 reads (14%) | called by muse, mutect2, varscan2
